Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RJ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RJ-01A (Primary Tumor).

ICD-O-3
Oligoastrocytoma, grade II
C8CE 938213
Site Brain, supratentorial NOS
C71.0
path
Brain, parietal lobe C71.3
gw 10/4/13

Nature of material: Brain
Received on:

Macroscopy:

Received in formalin, two fragments of soft and brown-brownish tissue measuring jointly 5.5 X 4.0 X 1.5 cm. Received, in the same vial, four smaller fragments, composed of soft and brownish tissue measuring jointly 1.0 X 0.8 X 0.3 cm.

Microscopy:

Sections stained with hematoxylin and eosin show brain tissue infiltrated by glial neoplasm with two distinct cellular patterns. One is represented by cells with round nuclei, loose chromatin and frequent clear perinuclear halos. Are arranged in bit fibrillar matrix which displays a network of support branched capillaries. The other pattern is formed by cells with irregular hyperchromatic nuclei and indistinct cytoplasm limits. They come up on fibrillar matrix with frequent cysts. It is note the occasional secondary structures of Scherer and some lymphocytic perivascular cuffs. It is not observed mitotic figures, necrotic foci or areas of microvascular proliferation. The lesion shows strong and diffuse positivity for GFAP and presents cellular proliferation index, estimated by Ki-67 immunostaining of about 1%.

Diagnosis:

Resection product of lesions in the parietal lobe (side not specified): - Oligoastrocitoma (grade II - WHO, 2007).

PROFESSIONAL PARTICIPANTS OF REPORT

Source: NCI Genomic Data Commons file f73493d7-c1cc-4552-ba4b-93674e9ea512 (TCGA-TQ-A7RJ.9C4E4467-F9B6-456F-8138-B81D42E6A5AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).